Surgical pathology report (de-identified scan), TCGA case TCGA-ZA-A8F6, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Candler, specimen TCGA-ZA-A8F6-01A (Primary Tumor).

[page 1 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT:
REG DR:

ACCT #:
AGE/SX: /M
DOB:
STATUS:

LOC:
ROOM:
BED:

SPEC #:

RECD:
COLL:

STATUS:

PERFORMED AT

TIME IN FORMALIN: 5:18 hrs.
COLD ISCHEMIA TIME: 0:00 mins.

Addendum # 1

The case is discussed with Dr. [REDACTED] by telephone. The gross specimen is reviewed in an attempt to find additional lymph nodes. Dissection reveals in the periserosal adipose tissue one area, possibly suspicious for metastatic tumor measuring 4 mm. No additional obvious gross lymph nodes are identified. The following additional sections are submitted:

- A10 - additional periserosal adipose tissue with suspicious nodule
- A11-15- additional periserosal adipose tissue

In the sections, four additional small lymph nodes are found, and these are negative for malignancy.

Addendum Signed _____ (signature on file) _____

ICD-O-3

Adenocarcinoma, intestinal type 8144/3
Site: Gastric antrum 816.3
7/24/14

[page 2 of 3]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry
Lab Database:

PAGE 2

SPEC #: PATIENT: (Continued)

CLINICAL INFORMATION:

Pre-Op Diagnosis: Gastric CA

Remarks:

Specimen(s): A. Subtotal gastrectomy for gross evaluation
B. Posterior vagus
C. Anterior vagus

MICROSCOPIC DIAGNOSIS

- A. PORTION DISTAL STOMACH, SUBTOTAL GASTRECTOMY:
- MODERATELY DIFFERENTIATED ADENOCARCINOMA
- TUMOR MEASURES 3 CM AND INFILTRATES MUSCULARIS
- SURGICAL MARGINS FREE OF TUMOR
- NO TUMOR SEEN IN ANY OF 3 REGIONAL LYMPH NODES
- SEE COMMENT FOR SYNOPTIC REPORT
- B. PORTION POSTERIOR VAGUS NERVE, VAGOTOMY:
- SEGMENT OF NERVE PRESENT
- C. PORTION ANTERIOR VAGUS NERVE, VAGOTOMY:
- SEGMENT OF NERVE PRESENT

COMMENT(S)

SURGICAL PATHOLOGY CANCER CASE SUMMARY - CAP APPROVED

Specimen:	Portion of stomach
Procedure:	Partial gastrectomy, distal
Tumor Site:	Antrum
Tumor Size:	3 cm in greatest dimension
Histologic Type:	Adenocarcinoma; intestinal type
Histologic Grade:	G2: Moderately differentiated
Microscopic Extent of Tumor:	Tumor invades muscularis propria
Margins:	Distance of carcinoma from closest margin: 6 cm: proximal
Treatment Effect:	No prior treatment
Lymph-Vascular Invasion:	Not identified
Pathologic Staging:	Primary Tumor: pT2 Regional Lymph Nodes: pN0 Number examined: 3 → + 4 = 7 Number involved: 0 Distant Metastasis: Not applicable

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry
Lab Database:

PAGE 3

SPEC #:

PATIENT:

(Continued)

GROSS DESCRIPTION:

The specimen is received in the fresh state from the operating room in three parts.

A. This is a subtotal gastrectomy specimen with adjacent tissues also resected. The stomach measures 15 x 7 x 3 cm. The proximal and distal margins are stapled closed. Present centrally is a red tumor which measures 3 x 2.5 x 1 cm. The tumor involves the wall but does not penetrate through the all and is located 6 cm from the proximal margin and 8 cm from the distal margin. Omentum attached to the specimen measures 18 x 18 x 4 cm. There is no gross evidence of metastatic tumor in the omentum. The surgeon has tagged subpyloric lymph node. No enlarged lymph nodes are found. Representative portions of the tumor are removed by aseptic technique and are submitted for tumor banking. The following sections are submitted:

- A1 - distal margin
- A2 - proximal margin
- A3,4 - whole prepyloric lymph node candidate
- A5 - red nodules in omentum
- A6-9 - gastric tumor

B. This is a 1 cm fragment of soft tissue, totally examined by frozen section as block B1.

C. This is a 1 cm fragment of soft tissue, totally examined by frozen section as block C1.

INTRAOPERATIVE CONSULTATION:

- A. IMMEDIATE GROSS EVALUATION, SUBTOTAL GASTRECTOMY:
- TUMOR PRESENT IN CENTRAL PORTION OF SPECIMEN
- SURGICAL MARGINS FREE OF TUMOR
- TUMOR PROCESSED FOR TUMOR BANKING
- B. FROZEN SECTION DIAGNOSIS, POSTERIOR VAGUE:
- PORTION OF NERVE PRESENT
- C. FROZEN SECTION DIAGNOSIS, ANTERIOR VAGUS:
- PORTION OF NERVE PRESENT

PHOTO DOCUMENTATION

Image : Picture Copy Error

Signed ____ (signature on file) ____

** END OF REPORT **

Primary Tumor Size Discrepancy		✓

Source: NCI Genomic Data Commons file 52371ff8-67a8-49cf-ad6d-90d43d2c215e (TCGA-ZA-A8F6.212608CC-A9ED-400A-A7C4-62E05B6B256F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).